Somatic mutation profile of tumor specimen C3L-00359-01 (aliquot CPT0002270008) from CPTAC case C3L-00359, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 73.5 years (26,864 days).
Specimen C3L-00359-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edcc8b8c-5702-46c8-969f-7fab9bbd085c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00359-31 (Blood Derived Normal), aliquot CPT0004370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14af9d6b-7c62-42bb-99fc-be752e7197ca

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Nonsense Mutation 2, Splice Site 1, 3'Flank 1, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 189/345 reads (55%) | catalogued as rs118203661, CM971522; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- DUSP2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372357109, COSV99997001; called by muse, mutect2, varscan2
- GCC1 | c.2116A>G p.I706V | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs771413693, COSV100365329; called by muse, mutect2, varscan2
- IGFLR1 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99495060; called by muse, mutect2, varscan2
- MOB2 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.043); catalogued as rs775310150; called by muse, mutect2, varscan2
- PARD3B | c.2914C>T p.P972S (on ENST00000406610 / NM_001302769.2; = p.P903S on NM_057177.7) | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs776299574, COSV62512300; called by muse, mutect2
- SLCO4C1 | c.466T>A p.C156S | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV60513297; called by muse, mutect2, varscan2
- SV2C | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs1561303070; called by muse, mutect2, varscan2
- TAOK3 | c.2538T>C p.I846= | Splice Region (SNP) | VAF 20/61 reads (33%) | catalogued as rs771985402; called by muse, mutect2, varscan2
- TPRA1 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.389); catalogued as rs899440348; called by muse, mutect2, varscan2
- TSC22D1 | c.3139T>C p.S1047P (on ENST00000458659 / NM_183422.4; = p.S118P on NM_006022.4) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs772780188, COSV54925546; called by muse, mutect2
- TSPAN1 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762027019, COSV64339800; called by muse, mutect2, varscan2
- WDSUB1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs766094209, COSV100701789; called by muse, mutect2, varscan2
- ACAT1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 119/406 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- APMAP | c.983G>C p.G328A | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- APMAP | c.982G>T p.G328W | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ATP5F1A | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP5F1A | c.817A>G p.I273V | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BRD8 | c.2146A>G p.I716V (on ENST00000254900 / NM_139199.2; = p.I789V on NM_006696.4) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CLK3 | c.1183_1189del p.L395Rfs*31 (on ENST00000395066 / NM_001130028.1; = p.L247Rfs*31 on NM_003992.4) | Frame Shift Del (DEL) | VAF 35/200 reads (18%) | called by mutect2, pindel, varscan2
- COL6A2 | c.2062A>G p.K688E | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNTL6 | c.1638+1G>A p.X546_splice | Splice Site (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- GATA6 | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GEMIN4 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GXYLT2 | c.1280G>T p.R427M | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ITGA11 | c.1978A>T p.K660* | Nonsense Mutation (SNP) | VAF 65/212 reads (31%) | called by muse, mutect2, varscan2
- MADD | c.3811C>A p.P1271T | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- MIDN | c.367A>G p.S123G | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MMAA | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZK1IP1 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLR2A | c.3692T>C p.I1231T | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- RSPO1 | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SBNO1 | c.2239T>C p.Y747H (on ENST00000420886; = p.Y746H on NM_018183.5) | Missense Mutation (SNP) | VAF 93/334 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCN10A | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 97/354 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.054); called by muse, varscan2
- SLC44A3 | c.113T>A p.F38Y | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TUBA3E | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ATAD2B | c.1719T>C p.P573= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs749028969; called by muse, mutect2
- BATF2 | c.798G>C p.L266= | Silent (SNP) | VAF 44/185 reads (24%) | called by muse, mutect2, varscan2
- CFAP77 | c.567T>C p.D189= | Silent (SNP) | VAF 143/243 reads (59%) | catalogued as rs1434146633; called by muse, mutect2, varscan2
- GPR155 | c.729T>C p.N243= | Silent (SNP) | VAF 63/238 reads (26%) | called by muse, mutect2, varscan2
- GPRASP2 | c.72T>A p.A24= | Silent (SNP) | VAF 57/145 reads (39%) | called by muse, mutect2, varscan2
- HELZ2 | c.3405G>A p.V1135= (on ENST00000467148 / NM_001037335.2; = p.V566= on NM_033405.3) | Silent (SNP) | VAF 55/227 reads (24%) | called by muse, mutect2, varscan2
- KIAA0319L | c.123C>T p.S41= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs550851202; called by muse, mutect2, varscan2
- MAN1C1 | c.183T>A p.P61= | Silent (SNP) | VAF 55/239 reads (23%) | called by muse, mutect2, varscan2
- MYO7A | c.3309G>A p.K1103= | Silent (SNP) | VAF 82/306 reads (27%) | called by muse, mutect2, varscan2
- NPR2 | c.462G>C p.V154= | Silent (SNP) | VAF 341/596 reads (57%) | called by muse, mutect2, varscan2
- OR2F1 | c.414A>T p.G138= | Silent (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- PPL | c.4842C>T p.S1614= | Silent (SNP) | VAF 57/435 reads (13%) | catalogued as rs557200041; called by muse, mutect2, varscan2
- TAMALIN | c.777C>T p.F259= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs766979803, COSV99530951; called by muse, mutect2, varscan2
- ZFYVE16 | c.3180A>G p.T1060= | Silent (SNP) | VAF 45/222 reads (20%) | called by muse, mutect2, varscan2
- ZMYM2 | c.1434T>C p.G478= | Silent (SNP) | VAF 47/201 reads (23%) | called by muse, mutect2, varscan2
- FAM149B1 | chr10:73247443 A>G | 3'Flank (SNP) | VAF 67/243 reads (28%) | catalogued as rs779710562; called by muse, mutect2, varscan2
- HBE1 | c.-267+159G>A | Intron (SNP) | VAF 20/144 reads (14%) | catalogued as COSV61163996; called by muse, mutect2, varscan2
